Somatic mutation profile of tumor specimen TCGA-AB-2895-03A (aliquot TCGA-AB-2895-03A-01W-0733-08) from TCGA case TCGA-AB-2895, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 41.9 years (15,310 days).
Specimen TCGA-AB-2895-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d01af06a-3bd4-48ee-a8e3-b01104477a3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2895-11A (Solid Tissue Normal), aliquot TCGA-AB-2895-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d753fc5-b70b-4eb1-887b-d32348058887

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 45/108 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 29/77 reads (38%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP10B | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58779196; called by muse, mutect2, varscan2
- CAND1 | c.2806T>G p.L936V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV73389659; called by muse, mutect2, varscan2
- DCAF8 | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1208295999, COSV58784424; called by muse, mutect2, varscan2
- DHX32 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV52940950; called by muse, mutect2, varscan2
- DOCK2 | c.1055+1G>A p.X352_splice | Splice Site (SNP) | VAF 66/132 reads (50%) | catalogued as rs1429834722, COSV56944648; called by muse, mutect2, varscan2
- FLT3 | c.1836T>A p.F612L | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.08); catalogued as COSV54057677; called by muse, varscan2
- GUCY2D | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54696742; called by muse, mutect2, varscan2
- PRDM16 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs768733228, COSV54594630; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3TC2 | c.3035G>A p.R1012Q | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs140666774; called by muse, mutect2, varscan2
- TBX18 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV63737201; called by muse, mutect2, varscan2
- CLASP2 | c.2896dup p.M966Nfs*4 (on ENST00000359576; = p.M965Nfs*4 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 90/234 reads (38%) | called by mutect2, varscan2
- ALDH16A1 | c.978G>A p.R326= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV53194647; called by muse, mutect2, varscan2
- FREM2 | c.6957C>T p.H2319= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as rs182710790, COSV54841215; called by muse, mutect2, varscan2
- GAS7 | c.954C>T p.C318= (on ENST00000432992 / NM_201433.2; = p.C178= on NM_003644.3) | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as rs775354427, COSV100094885, COSV60438000; called by muse, mutect2, varscan2
- LDLRAD3 | c.975C>T p.G325= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as COSV59683706; called by muse, mutect2, varscan2
- MED24 | c.645C>A p.A215= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV62419237; called by muse, mutect2, varscan2
- MYH2 | c.1275C>T p.N425= | Silent (SNP) | VAF 146/270 reads (54%) | catalogued as rs151000841; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSKU | c.237G>A p.A79= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as rs764724433, COSV60752039; called by muse, mutect2, varscan2
